Gene-level copy-number profile of tumor specimen TCGA-62-A46O-01A from TCGA case TCGA-62-A46O, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.8 years (24,050 days).
Specimen TCGA-62-A46O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e07fa841-db4a-448d-9906-a5b2fe750c36.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-62-A46O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6f7ad499-6128-4ea6-8c83-41e49fd3e0c5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,253; copy number 2: 21,365; copy number 3: 21,399; copy number 4: 12,189; copy number 5: 1,488; copy number 6: 1,104; copy number 7: 30; copy number 8: 134; copy number 9: 386; copy number 10: 284; copy number 11: 171.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-62-A46O-01A-11D-A24C-01): tumor purity 0.82, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,967,752–22,128,103, 7 genes: CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,005 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,887,890–152,709,491, 147 genes, copy number 9 (broad region; genes not listed).
- chr2:119,223,831–120,710,517, 30 genes, copy number 7: STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1.
- chr17:59,841,266–59,950,574, 6 genes, copy number 8 (within-gene range 3–8): MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21.
- chr19:35,550,031–37,906,677, 127 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr19:37,963,853–37,964,790, 1 gene, copy number 8: AC008395.1.
- chr19:40,991,282–46,260,858, 283 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr22:19,330,698–25,729,294, 410 genes, copy number 9–10 (broad region; genes not listed).
- chr22:25,756,318–25,756,669, 1 gene, copy number 10: AL022329.3.

Autosomal genes at a single copy (total copy number 1): 1,246. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
